Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A2HJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A2HJ-01A (Primary Tumor).

[page 1 of 5]
1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1 w 4/19/11

Name: [REDACTED] Sex: F DOB: ([REDACTED]) MRUN: [REDACTED]
Loc: [REDACTED] Adm: [REDACTED] Att: [REDACTED] Acc#: [REDACTED]

Acct#: [REDACTED]

Ord #: [REDACTED] *ASAP*/RESULTED Collect D/T=

SURGICAL PATHOLOGY

Modifiers:

(1 of 1)

SURGICAL PATHOLOGY:

CoPath Specimen :

Source:

- A: Uterus, cervix +/- tubes/ovaries, (f/s)
- B: Anterior Vaginal margin
- C: Posterior Vaginal margin
- D: Left Pelvic lymph node
- E: Left Peri-aortic lymph node
- F: Right Pelvic lymph node
- G: Right Peri-aortic lymph node

Final Diagnosis

A. Uterus, cervix, ovaries, and fallopian tubes, F/S (TAH/BSO):
UTERUS:

- Endometrial adenocarcinoma, endometrioid type, moderately differentiated, FIGO grade 3.
- Tumor site: Anterior and posterior endometrium
- Tumor size: 7.2 X 6.3 X 2.5 cm
- Tumor invades more than two thirds of the myometrium (2.2 cm invasion depth/ 2.5 cm myometrial thickness) or 88% of myometrial wall.
- Foci suspicious for lymphovascular invasion are seen.
- Right and left parametria are negative for tumor.
- Margins are uninvolved by invasive carcinoma
- Distance of invasive carcinoma from closest margin: 3 mm (Anterior serosa).

CERVIX:

- Acute and chronic cervicitis.
- Negative for carcinoma.

OVARIES AND FALLOPIAN TUBES:

- Follicular cysts
- Negative for carcinoma.

Pathologic TNM stage (AJCC 2002): T1b N0 MX.

B. Anterior vaginal margin (excision):

- Squamous mucosa with mild chronic inflammation.
- Negative for malignancy.

C. Posterior vaginal margin (excision):

- Squamous mucosa with focal acute and chronic inflammation.
- Negative for malignancy.

[page 2 of 5]
Name [REDACTED] Sex: F DOB: [REDACTED]
Loc: [REDACTED] Adm: [REDACTED] Att: [REDACTED] MRUN [REDACTED]
Acc#: [REDACTED]

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED]

- D. Left pelvic lymph node (excision):
- Three lymph nodes, negative for metastatic carcinoma (0/3).
- E. Left periaortic lymph node (excision):
- Two lymph nodes, negative for metastatic carcinoma (0/3).
- F. Right pelvic lymph node (excision):
- Four lymph nodes, negative for metastatic carcinoma (0/4).
- G. Right periaortic lymph node (excision):
- Eight lymph nodes, negative for metastatic carcinoma (0/8).

Comment:

The frozen section of the right ovary had an area that was suspicious for metastatic carcinoma. However, on permanent section that area turned out to be only a solid collection of follicular cells.

***Electronically Signed Out

Clinical History

female with endometrial cancer.

Pre Operative Diagnosis
Endometrial cancer.

Operation Performed
EUA; Ex-Lap; TAH/BSO; BLPPALND

Operative Findings
18 week globular uterus, enlarged right ovary; same prominent lymph nodes.

Post Operative Diagnosis
Same.

Intraoperative Diagnosis
Frozen Section:

#1 and 2:

Uterus Endometrial adenocarcinoma, grade 2-3, infiltrating

[page 3 of 5]
Name: [REDACTED] Sex: F DOB: [REDACTED]
Loc: [REDACTED] Adm: [REDACTED] Att: [REDACTED] MRUN: [REDACTED]
Acc#: [REDACTED]

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED]

approximately 80% of myometrial wall.

3. Right ovary Foci highly suspicious for metastatic carcinoma.

Gross Description

The specimen is submitted in 7 parts, labeled "

Specimen A is received fresh for frozen section, labeled "uterus, cervix, BSO". It consists of a hysterectomy and bilateral salpingo-oophorectomy specimen weighing 266 grams. The uterus measures 9.5 cm from superior to inferior, 7.2 cm from cornu to cornu and 6.5 cm from anterior to posterior. The serosal surface is pink-tan and smooth. The anterior surface of the uterus is inked blue and the posterior surface is inked black. The uterus is opened with a Y-shaped incision to reveal a soft, pink-red, hemorrhagic, irregular, tumor mass, occupying the entire endometrial cavity. The mass measures 7.2 X 6.3 X 2.5 cm. The endocervical canal measures 3.1 cm in length. The endocervical mucosa is pink-red and hemorrhagic. The anterior myometrium measures 2.5 cm in thickness and the posterior myometrium measures 2.2 cm in thickness. The tumor infiltrates deep into the anterior myometrium and measures up to 2.2 cm into the myometrium. The right fallopian tube measures 7.5 cm in length and 0.2 cm in average diameter. The right ovary is pink-tan, enlarged with a smooth serosal surface. The right ovary measures 4.1 X 2.2 X 1.7 cm. The ovary is bisected to reveal a cystic sectioned surface with central firm, pink-tan areas. The cysts measure 0.2 to 0.6 cm in greatest dimension. The left fallopian tube measures 6.5 cm in length and 0.3 cm in average diameter. The left ovary is pink-tan, enlarged with a smooth outer surface. The left ovary measures 4.0 X 2.2 X 2.0 cm. The left ovary is bisected to reveal a firm, pink-tan sectioned surface with multiple cysts that range in size from 0.3 to 0.4 cm in greatest dimension. A representative section of the tumor from the anterior wall, including the myometrium, is submitted for frozen section. The tumor with the myometrium is submitted as frozen section 1 and the remainder of tissue is entirely submitted in -A1. The tumor mass with the endometrium is submitted as frozen section 2 and the remaining

[page 4 of 5]
Name [REDACTED] Sex: F DOB: [REDACTED] MRUN [REDACTED]
Loc: [REDACTED] Adm: [REDACTED] Att: [REDACTED] Acc#: [REDACTED]

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED]

tissue is entirely submitted as [REDACTED]-A2. A representative section of the right ovary is submitted for frozen section and the remainder of the tissue is submitted as [REDACTED] A3. Representative sections are submitted for microscopic examination as follows:

Cassette Summary:

- A4 anterior cervix,
- A5 posterior cervix,
- A6 anterior lower uterine segment with tumor,
- A7 posterior lower uterine segment with tumor,
- A8 representative section from the tumor,
- A9 anterior endomyometrium to serosa with tumor,
- A10 posterior endomyometrium to serosa with tumor,
- A11 a representative section of tumor,
- A12 right ovary,
- A13 right fallopian tube,
- A14 left ovary,
- A15 left fallopian tube
- A16 - right parametrium
- A17 - left parametrium

Specimen B is received in formalin, labeled "anterior vaginal margin". It consists of an elongated piece of tan tissue, measuring 1.5 X 0.8 X 0.3 cm. The specimen is entirely submitted in B1.

Specimen C is received in formalin, labeled "posterior vaginal margin". It consists of an irregular piece of pink-tan tissue, measuring 0.8 X 0.3 X 0.3 cm. The specimen is entirely submitted in C1.

Specimen D is received in formalin, labeled "pelvic lymph node". It consists of two irregular pieces of fatty tissue, measuring in aggregate 3.5 X 2.5 X 1.2 cm. Three lymph nodes are identified, measuring 1.5, 1.7, and 5.1 cm in greatest dimension. The lymph nodes are entirely submitted as follows:
D1 two lymph nodes, one bisected, D2 and D3 one lymph node sectioned into 4 pieces.

Specimen E is received in formalin, labeled as "left periaortic lymph node". It consists of multiple irregular pieces of fibro-lymphoid tissue, measuring in aggregate 2.7 X 1.4 X 0.6 cm. Two lymph nodes are identified, measuring 1.4 and 1.0 cm in

[page 5 of 5]
Name [REDACTED] Sex: F DOB: [REDACTED]
Loc: [REDACTED] Adm: [REDACTED] Att: [REDACTED] MRUN [REDACTED]
Acc#: [REDACTED]

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED]

greatest dimension. The lymph nodes are entirely submitted as follows: E1 one lymph node bisected, E2 one lymph node bisected.

Specimen F is received in formalin, labeled "right pelvic lymph node". It consists of an irregular piece of fibro-lymphoid tissue, measuring 2.7 X 1.8 X 0.8 cm. Two lymph nodes are identified, measuring 2.1 X 1.3 X 2.5 cm and 0.8 X 0.3 X 0.3 m. The lymph nodes are entirely submitted as follows: F1 and F2 one lymph node bisected, F3 one lymph node with entire remaining fatty tissue.

Specimen G is received in formalin, labeled "right periaortic lymph node". It consists of an irregular piece of fibrofatty tissue, measuring 2.6 X 1.6 X 0.3 cm. Three lymph nodes are identified, measuring 0.8, 1.0 and 0.5 cm in greatest dimension.

The specimen is entirely submitted as follows: G1 one lymph node, G2 one lymph node, bisected, G3 one lymph node with entire remaining fatty tissue.

Microscopic Description

Microscopic Examination was performed.

Source: NCI Genomic Data Commons file cb4b375c-5f5c-4b5c-a456-466a8b624ce0 (TCGA-AX-A2HJ.84FF1AB9-47F4-4884-9345-43878BDEF379.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).